Somatic mutation profile of tumor specimen TCGA-DO-A1JZ-01A (aliquot TCGA-DO-A1JZ-01A-11D-A13W-08) from TCGA case TCGA-DO-A1JZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 23.4 years (8,551 days).
Specimen TCGA-DO-A1JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d27152b5-cf0a-4428-a05a-9d84babeaa60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DO-A1JZ-10A (Blood Derived Normal), aliquot TCGA-DO-A1JZ-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf47ff3e-8821-4709-985b-8a8076340611

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEIL3 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs1181188322, COSV52813492; called by muse, mutect2, varscan2
- POLR1A | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447759486, COSV55697594; called by muse, mutect2, varscan2
- TP53BP1 | c.2926G>T p.G976W | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as COSV55505069, COSV55508806; called by muse, mutect2, varscan2
